Somatic mutation profile of tumor specimen TARGET-10-PARSRI-09A (aliquot TARGET-10-PARSRI-09A-01D) from TARGET case TARGET-10-PARSRI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,649 days).
Specimen TARGET-10-PARSRI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad8ded8a-4e53-4d47-af52-9e7552961d26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARSRI-10A (Blood Derived Normal), aliquot TARGET-10-PARSRI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a061cd8d-bc25-452f-818b-be6457e249bc

The open-access MAF lists 29 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 5, Silent 4, 5'UTR 1, Splice Site 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK1 | c.1972G>T p.V658F | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519753, COSV61086927, COSV61091213; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.9280G>A p.V3094I | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as rs769176550, COSV55076939; called by muse, mutect2, varscan2
- C1orf87 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs761108345; called by muse, mutect2, varscan2
- FAM71E2 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs948240911, COSV99214943; called by muse, mutect2, varscan2
- HLCS | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375000063; called by muse, mutect2, varscan2
- IDE | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56421587; called by muse, mutect2
- IGSF9B | c.2417A>G p.K806R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.48); catalogued as rs772586048; called by mutect2, varscan2
- MAPK8IP2 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1367549427; called by muse, mutect2, varscan2
- MS4A18 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1012272496; called by muse, mutect2, varscan2
- ROS1 | c.4417A>C p.T1473P | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV63861232; called by muse, mutect2, varscan2
- SLC19A3 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 82/153 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.378); catalogued as rs758707665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRL3 | c.1648A>T p.T550S (on ENST00000506720 / NM_001322402.2; = p.T482S on NM_015236.6) | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- MAD1L1 | c.302A>G p.D101G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MUC19 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NLRP6 | c.2373-2A>G p.X791_splice | Splice Site (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- UBE4B | c.1972C>G p.L658V (on ENST00000343090 / NM_001105562.3; = p.L529V on NM_006048.5) | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP9X | c.1300del p.I434Sfs*13 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by pindel*, varscan2
- ZP4 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ARHGAP39 | c.2448G>A p.P816= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs762965371; called by muse, mutect2, varscan2
- C1S | c.1296T>C p.F432= | Silent (SNP) | VAF 42/78 reads (54%) | called by muse, mutect2, varscan2
- SETBP1 | c.4050G>A p.K1350= | Silent (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- ZNF831 | c.624C>T p.G208= | Silent (SNP) | VAF 11/147 reads (7%) | catalogued as COSV64039746; called by muse, mutect2
- ACSL6 | c.1885-55C>G | Intron (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- FAM90A28P | n.504G>A | RNA (SNP) | VAF 37/59 reads (63%) | catalogued as rs1300683364; called by muse, mutect2, varscan2
- KCTD1 | c.-15-46430G>A | Intron (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- P2RX1 | c.525-63T>C | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- SGCA | c.983+876G>A | Intron (SNP) | VAF 38/80 reads (48%) | catalogued as rs758946738, COSV56250196; called by muse, mutect2, varscan2
- SLC6A1 | c.-6C>T | 5'UTR (SNP) | VAF 14/31 reads (45%) | catalogued as rs961590033, COSV99822856; called by muse, mutect2, varscan2
- WDR45 | c.236-25G>A | Intron (SNP) | VAF 28/64 reads (44%) | catalogued as rs782245609; called by muse, mutect2, varscan2
